Gene-level copy-number profile of specimen HCM-BROD-0253-C15-85B from HCMI case HCM-BROD-0253-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.3 years (28,216 days).
Specimen HCM-BROD-0253-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f0610fc-e6ba-4ebc-8186-34ce5e46c7c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0253-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/640eecde-ff6e-495c-ad04-7b74b50cc546

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2; copy number 2: 20,147; copy number 3: 30,871; copy number 4: 6,178; copy number 5: 1,408; copy number 6: 28; copy number 7: 17; copy number 8: 200; copy number 9: 10; copy number 11: 34; copy number 14: 7; copy number 16: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:6,996,766–7,018,297, 3 genes: DEFA1B, DEFT1P2, DEFA3.
- chr9:21,480,839–21,482,313, 1 gene (within-gene range 0–2): IFNE.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 271 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:20,923,222–22,317,176, 61 genes, copy number 7–16 (broad region; genes not listed).
- chr20:32,561,093–38,450,940, 200 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:25,742,144–26,031,045, 3 genes, copy number 7 (within-gene range 4–7): MYO18B, AL022329.3, MYO18B-AS1.
- chr22:26,644,889–26,676,475, 6 genes, copy number 7 (within-gene range 6–7): ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2.
- chr22:26,673,254–26,673,630, 1 gene, copy number 7 (within-gene range 6–7): Z99774.3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
